Gene-level copy-number profile of tumor specimen C3L-07671-01 from CPTAC case C3L-07671, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.0 years (18,272 days).
Specimen C3L-07671-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 074c9817-d183-4b36-a45d-073430b6e5b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07671-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/64bb81cc-c8b9-4c21-932c-1ea0c4ab75ab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,450; copy number 2: 21,530; copy number 3: 28,113; copy number 4: 6,671; copy number 5: 277; copy number 6: 18; copy number 7: 416; copy number 8: 46; copy number 9: 21; copy number 10: 280; copy number 11: 29; copy number 13: 8; copy number 23: 15; copy number 119: 9; copy number 134: 8.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:69,631,963–69,985,501, 6 genes: AC139495.2, GUSBP3, AC139495.1, GUSBP13, AC131392.1, CDH12P2.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:9,090,898–9,442,380, 2 genes (within-gene range 0–2): RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 832 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:18,242,961–25,250,936, 97 genes, copy number 8–23 (within-gene range 3–23) (broad region; genes not listed).
- chr19:14,941,489–15,662,825, 34 genes, copy number 7–8: OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3.
- chr20:35,433,029–64,327,972, 701 genes, copy number 7–134 (within-gene range 7–197) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,450. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
